Somatic mutation profile of tumor specimen TCGA-B0-5119-01A (aliquot TCGA-B0-5119-01A-02D-1421-08) from TCGA case TCGA-B0-5119, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 61.9 years (22,607 days).
Specimen TCGA-B0-5119-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 97bcf7bd-c1ff-4223-957b-b103374fba75.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5119-11A (Solid Tissue Normal), aliquot TCGA-B0-5119-11A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/48d726e6-c6ba-40b2-9f62-e4f41372b337

The open-access MAF lists 93 somatic variants for this specimen: 75 protein-altering or splice-affecting, 15 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 15, Frame Shift Del 11, Nonsense Mutation 3, Splice Site 2, In Frame Del 2, Frame Shift Ins 2, RNA 1, 5'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADSL | c.76A>C p.M26L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.245); catalogued as CM990116, COSV53406540; called by muse, mutect2, varscan2
- AKAP17A | c.521T>C p.L174P | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV58308105; called by muse, mutect2, varscan2
- AKAP6 | c.5008G>T p.G1670C | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55204072; called by muse, mutect2, varscan2
- AKAP6 | c.5009G>T p.G1670V | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV55204091; called by muse, mutect2, varscan2
- AL592490.1 | c.2735G>C p.C912S | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as COSV69424399; called by muse, varscan2
- ANO10 | c.992A>G p.Y331C | Missense Mutation (SNP) | VAF 42/78 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV52728177; called by muse, mutect2, varscan2
- ATP1B4 | c.416G>A p.S139N (on ENST00000218008 / NM_001142447.3; = p.S135N on NM_012069.5) | Missense Mutation (SNP) | VAF 213/726 reads (29%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV54311080; called by muse, mutect2, varscan2
- B4GALT6 | c.777-2A>C p.X259_splice | Splice Site (SNP) | VAF 48/151 reads (32%) | catalogued as COSV52702555; called by muse, mutect2, varscan2
- BORA | c.505G>C p.D169H (on ENST00000613797; = p.D94H on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV64694818; called by muse, mutect2, varscan2
- CDKN1A | c.279G>C p.R93S | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as COSV55186693, COSV55190318; called by muse, mutect2, varscan2
- CHFR | c.937G>A p.D313N (on ENST00000432561 / NM_001161345.1; = p.D272N on NM_018223.2) | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV57171873; called by muse, mutect2, varscan2
- COL8A2 | c.1730T>G p.F577C | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57440608; called by muse, mutect2, varscan2
- COQ8A | c.1660-2A>T p.X554_splice | Splice Site (SNP) | VAF 30/89 reads (34%) | catalogued as COSV62001709; called by muse, mutect2, varscan2
- DCN | c.860G>T p.G287V | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV50006030, COSV50008234, COSV99271780; called by muse, mutect2, varscan2
- DNAH10 | c.1483A>T p.K495* (on ENST00000409039; = p.K434* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as COSV68987525, COSV68996854; called by muse, mutect2, varscan2
- EIF3M | c.308T>C p.L103P | Missense Mutation (SNP) | VAF 106/340 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV60072285; called by muse, mutect2, varscan2
- FSTL1 | c.202A>C p.S68R | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55231834; called by muse, mutect2, varscan2
- GOLGA6A | c.1972C>A p.L658M | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99297066; called by muse, mutect2, varscan2
- IFTAP | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV57556243; called by muse, mutect2, varscan2
- IRAK1 | c.1642G>A p.V548M | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.59); PolyPhen benign (0.027); catalogued as rs140583367, COSV64110022; called by muse, mutect2, varscan2
- LAMA2 | c.8860G>C p.G2954R | Missense Mutation (SNP) | VAF 4/98 reads (4%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.538); catalogued as COSV70337657, COSV70355990; called by muse, mutect2
- LAMC3 | c.1244G>C p.C415S | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63088405; called by muse, mutect2, varscan2
- MLLT10 | c.1760C>T p.S587F (on ENST00000307729 / NM_001195626.3; = p.S603F on NM_004641.3) | Missense Mutation (SNP) | VAF 79/239 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV56990567; called by muse, mutect2, varscan2
- MRC2 | c.2399G>A p.C800Y | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1475822596, COSV57636404; called by muse, mutect2, varscan2
- MTOR | c.2580G>T p.K860N | Missense Mutation (SNP) | VAF 8/232 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as COSV63868180; called by muse, mutect2
- MYO1F | c.2471T>A p.L824H | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57791636; called by muse, mutect2, varscan2
- MYO5C | c.3859G>A p.E1287K | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs868392874, COSV55902314; called by muse, mutect2, varscan2
- NAALADL2 | c.467C>G p.S156C | Missense Mutation (SNP) | VAF 91/272 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as COSV70794356; called by muse, mutect2, varscan2
- NOS1 | c.2038G>A p.D680N | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768333861, COSV57606310; called by muse, mutect2, varscan2
- OLFM1 | c.499G>C p.V167L (on ENST00000371793 / NM_001282611.2; = p.V149L on NM_014279.5) | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.97); catalogued as COSV52961470; called by muse, mutect2, varscan2
- OR2W1 | c.871A>T p.T291S | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.695); catalogued as COSV65851370; called by muse, mutect2, varscan2
- OR7G1 | c.916G>T p.G306C | Missense Mutation (SNP) | VAF 68/227 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV53316905; called by muse, mutect2, varscan2
- OR7G1 | c.439C>G p.L147V | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.1); catalogued as COSV53316919, COSV99528731; called by muse, mutect2, varscan2
- OSGIN2 | c.1406A>G p.N469S | Missense Mutation (SNP) | VAF 19/290 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.266); catalogued as rs1183333932, COSV52406952; called by muse, mutect2
- PAK4 | c.940C>A p.P314T | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.224); catalogued as COSV58943616; called by muse, mutect2, varscan2
- PAPOLG | c.1744C>T p.L582F | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.359); catalogued as COSV53181145; called by muse, mutect2, varscan2
- PI4KA | c.2049T>G p.S683R | Missense Mutation (SNP) | VAF 85/251 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV55403403; called by muse, mutect2, varscan2
- PLOD2 | c.700G>C p.E234Q | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as COSV51461934; called by muse, mutect2, varscan2
- PPP1R15B | c.226G>T p.G76* | Nonsense Mutation (SNP) | VAF 46/181 reads (25%) | catalogued as COSV65815187; called by muse, mutect2, varscan2
- PRKD2 | c.2572G>C p.G858R | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.176); catalogued as COSV52184418; called by muse, mutect2, varscan2
- PSD3 | c.2381G>A p.R794Q (on ENST00000440756; = p.R793Q on NM_015310.4) | Missense Mutation (SNP) | VAF 64/235 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs775463347, COSV54068829, COSV54076333; called by muse, mutect2, varscan2
- PTPRH | c.3233G>A p.R1078Q | Missense Mutation (SNP) | VAF 65/240 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.761); catalogued as COSV54742428, COSV99670655; called by muse, mutect2, varscan2
- RBBP5 | c.758C>A p.P253Q | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT tolerated (0.75); PolyPhen benign (0.013); catalogued as COSV52702651; called by muse, mutect2, varscan2
- RECQL5 | c.2546A>T p.D849V | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as COSV58637088; called by muse, mutect2, varscan2
- REXO5 | c.1491G>T p.M497I | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV54470597; called by muse, mutect2, varscan2
- RGL1 | c.377A>G p.E126G (on ENST00000360851 / NM_001297672.2; = p.E161G on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 71/245 reads (29%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.982); catalogued as COSV58978432; called by muse, mutect2, varscan2
- RUBCNL | c.1633G>T p.A545S | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.216); catalogued as COSV59784913; called by muse, mutect2, varscan2
- SAR1B | c.469A>T p.T157S | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as COSV68391271; called by muse, varscan2
- SHROOM1 | c.2317G>A p.V773M (on ENST00000378679 / NM_001172700.2; = p.V768M on NM_133456.2) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as rs1561446838, COSV60580381, COSV60581883; called by muse, mutect2
- SMYD2 | c.1249G>A p.G417S | Missense Mutation (SNP) | VAF 56/175 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778741699, COSV65290309; called by muse, mutect2, varscan2
- SULF1 | c.740C>G p.P247R | Missense Mutation (SNP) | VAF 61/190 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.754); catalogued as COSV52672412, COSV52681482; called by muse, mutect2, varscan2
- THEMIS | c.359A>G p.Q120R | Missense Mutation (SNP) | VAF 83/165 reads (50%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV64069118; called by muse, mutect2, varscan2
- TJP1 | c.2836A>T p.N946Y | Missense Mutation (SNP) | VAF 68/216 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.1); catalogued as COSV62039158; called by muse, mutect2, varscan2
- TRAPPC8 | c.2677del p.T893Hfs*11 | Frame Shift Del (DEL) | VAF 46/198 reads (23%) | catalogued as COSV99352052; called by mutect2, pindel, varscan2
- UBN1 | c.226A>C p.K76Q | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); catalogued as COSV52165532; called by muse, mutect2, varscan2
- VCPIP1 | c.262G>T p.V88L | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); catalogued as COSV60045934; called by muse, mutect2, varscan2
- VCPIP1 | c.261G>C p.E87D | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV60045946; called by muse, mutect2, varscan2
- VPS35L | c.115A>C p.T39P | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as COSV51976607; called by muse, mutect2, varscan2
- WDR25 | c.228T>A p.Y76* | Nonsense Mutation (SNP) | VAF 38/99 reads (38%) | catalogued as COSV58933693; called by muse, mutect2, varscan2
- ZBTB49 | c.647T>G p.L216R | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61924211; called by muse, mutect2, varscan2
- ZNF816 | c.1675C>T p.H559Y | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV54410320; called by muse, mutect2, varscan2
- AL592490.1 | c.2806del p.I936Lfs*30 | Frame Shift Del (DEL) | VAF 50/202 reads (25%) | called by pindel, varscan2
- ASXL2 | c.1289_1292del p.E430Vfs*91 | Frame Shift Del (DEL) | VAF 147/590 reads (25%) | called by mutect2, pindel, varscan2
- COL6A6 | c.3347del p.D1116Afs*10 | Frame Shift Del (DEL) | VAF 30/128 reads (23%) | called by mutect2, pindel, varscan2
- FBXO43 | c.1080del p.K361Nfs*12 | Frame Shift Del (DEL) | VAF 85/285 reads (30%) | called by mutect2, pindel, varscan2
- PCK1 | c.1718_1720del p.N573del | In Frame Del (DEL) | VAF 15/71 reads (21%) | called by mutect2, pindel, varscan2
- PIWIL3 | c.1555_1558del p.H519Efs*6 | Frame Shift Del (DEL) | VAF 128/464 reads (28%) | called by mutect2, pindel, varscan2
- RICTOR | c.1517del p.Q506Rfs*24 | Frame Shift Del (DEL) | VAF 79/283 reads (28%) | called by mutect2, pindel, varscan2
- RNASE7 | c.248_249insGCGCCACCTG p.C83Wfs*16 | Frame Shift Ins (INS) | VAF 13/74 reads (18%) | called by mutect2, varscan2
- SHCBP1 | c.269del p.L90* | Frame Shift Del (DEL) | VAF 26/85 reads (31%) | called by mutect2, pindel, varscan2
- SLC11A2 | c.1604_1607del p.A535Dfs*24 (on ENST00000394904 / NM_001379455.1; = p.A506Dfs*24 on NM_000617.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 24/86 reads (28%) | called by pindel, varscan2
- SPG7 | c.1677del p.E560Nfs*25 (on ENST00000268704; = p.E567Nfs*25 on NM_003119.4) | Frame Shift Del (DEL) | VAF 37/136 reads (27%) | called by mutect2, pindel, varscan2
- TOGARAM2 | c.67_69del p.I23del | In Frame Del (DEL) | VAF 6/20 reads (30%) | called by mutect2, varscan2
- USPL1 | c.1866_1867del p.N623Yfs*18 | Frame Shift Del (DEL) | VAF 34/121 reads (28%) | called by mutect2, pindel, varscan2
- WDR33 | c.1165_1166dup p.L390Ffs*29 | Frame Shift Ins (INS) | VAF 51/196 reads (26%) | called by mutect2, pindel, varscan2
- ACAN | c.201C>G p.A67= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as COSV61355402; called by muse, mutect2, varscan2
- BICC1 | c.1488A>G p.T496= | Silent (SNP) | VAF 80/281 reads (28%) | catalogued as COSV54061769; called by muse, mutect2, varscan2
- CACNA1G | c.1185C>T p.A395= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV61719964; called by muse, mutect2, varscan2
- CELSR1 | c.4749C>A p.G1583= | Silent (SNP) | VAF 45/122 reads (37%) | catalogued as COSV53083094; called by muse, mutect2, varscan2
- F2R | c.831C>A p.V277= | Silent (SNP) | VAF 53/174 reads (30%) | catalogued as COSV59928233; called by muse, mutect2, varscan2
- ITPR3 | c.2802C>T p.S934= | Silent (SNP) | VAF 22/83 reads (27%) | catalogued as rs370555491; called by muse, mutect2, varscan2
- NGF | c.189G>T p.V63= | Silent (SNP) | VAF 28/65 reads (43%) | catalogued as COSV65686787, COSV65687921; called by muse, mutect2, varscan2
- OIT3 | c.849T>C p.G283= | Silent (SNP) | VAF 94/280 reads (34%) | catalogued as COSV61824945; called by muse, mutect2, varscan2
- PPP2R1B | c.1119C>A p.T373= | Silent (SNP) | VAF 40/113 reads (35%) | catalogued as COSV59534573; called by muse, mutect2, varscan2
- PPP6R3 | c.393T>C p.L131= | Silent (SNP) | VAF 73/227 reads (32%) | catalogued as COSV55720796; called by muse, mutect2, varscan2
- PTPRZ1 | c.2178T>C p.H726= | Silent (SNP) | VAF 10/170 reads (6%) | catalogued as COSV66429783; called by muse, mutect2
- RAD51 | c.168A>T p.P56= | Silent (SNP) | VAF 66/203 reads (33%) | catalogued as COSV51110941; called by muse, mutect2, varscan2
- STK11 | c.522C>T p.H174= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV58820085; called by muse, mutect2, varscan2
- TELO2 | c.1785G>T p.L595= | Silent (SNP) | VAF 58/195 reads (30%) | catalogued as COSV51975897; called by muse, mutect2, varscan2
- VPS13B | c.9825A>G p.P3275= | Silent (SNP) | VAF 57/187 reads (30%) | catalogued as rs764864362, COSV62132395; called by muse, mutect2, varscan2
- NRG1 | c.502+30876G>C | Intron (SNP) | VAF 17/60 reads (28%) | catalogued as COSV55147646; called by muse, mutect2, varscan2
- OR2H2 | chr6:29582303 G>A | 5'Flank (SNP) | VAF 34/78 reads (44%) | catalogued as rs747582404, COSV63280614; called by muse, mutect2, varscan2
- TMEM183B | n.623A>G | RNA (SNP) | VAF 120/369 reads (33%) | called by muse, mutect2, varscan2
